Gene-level copy-number profile of tumor specimen TCGA-25-1313-01A from TCGA case TCGA-25-1313, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 62.9 years (22,982 days).
Specimen TCGA-25-1313-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.568acf95-5e03-406b-ac0d-4d0e7d6855eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1313-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5e20c37-1f83-4c32-ac62-2d281f88738e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 1,557; copy number 2: 21,700; copy number 3: 14,921; copy number 4: 11,097; copy number 5: 7,965; copy number 6: 2,353; copy number 7: 146; copy number 9: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-1313-01A-01D-0452-01): tumor purity 0.56, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,035,587, 45 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,493 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,141,515–47,704,029, 415 genes, copy number 5–6 (broad region; genes not listed).
- chr1:47,761,132–47,765,547, 1 gene, copy number 6: AL691459.1.
- chr1:85,729,233–86,156,943, 1 gene, copy number 5 (within-gene range 4–5): COL24A1.
- chr1:86,029,854–96,823,738, 203 genes, copy number 5 (broad region; genes not listed).
- chr1:143,343,180–199,021,037, 1,458 genes, copy number 5–9 (broad region; genes not listed).
- chr1:232,804,892–248,919,946, 380 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–342,118, 9 genes, copy number 6: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865.
- chr2:165,433,438–202,619,896, 588 genes, copy number 5 (broad region; genes not listed).
- chr2:234,952,017–242,160,153, 165 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:87,227,271–102,479,841, 163 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:148,791,102–160,228,213, 220 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–14,599,690, 272 genes, copy number 5–6 (broad region; genes not listed).
- chr6:15,934,782–50,637,205, 1,116 genes, copy number 5–6 (broad region; genes not listed).
- chr7:65,814,672–66,915,334, 43 genes, copy number 6: RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP.
- chr7:78,017,055–79,453,667, 9 genes, copy number 5 (within-gene range 4–5): MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P.
- chr7:144,048,948–159,233,377, 291 genes, copy number 6 (broad region; genes not listed).
- chr8:49,909,789–145,066,685, 1,463 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr9:60,914,407–77,421,537, 284 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr9:105,244,622–110,337,884, 70 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:110,369,592–110,369,698, 1 gene, copy number 5: RNU6-1039P.
- chr10:110,567,695–111,105,248, 17 genes, copy number 5: SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1.
- chr10:130,505,106–130,537,406, 2 genes, copy number 6: Y_RNA, AC016816.1.
- chr11:71,673,885–97,259,987, 571 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:98,565,074–98,566,827, 1 gene, copy number 5: AP003038.1.
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 3–5): NRXN3.
- chr14:79,072,132–82,746,664, 37 genes, copy number 5 (within-gene range 4–5): AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1, AF123462.1, DIO2, DIO2-AS1, CEP128, HMGN2P2, TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2.
- chr14:97,427,071–106,875,071, 536 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:59,049,399–66,565,979, 197 genes, copy number 6 (broad region; genes not listed).
- chr15:78,250,502–91,605,873, 384 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:78,605,233–83,095,122, 205 genes, copy number 5 (broad region; genes not listed).
- chr18:70,205,774–77,277,900, 109 genes, copy number 5 (broad region; genes not listed).
- chr19:50,505,998–57,578,911, 539 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–25,149,372, 500 genes, copy number 5–6 (broad region; genes not listed).
- chr20:50,510,321–62,861,822, 242 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
